Surgical pathology report (de-identified scan), TCGA case TCGA-CL-4957, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Harvard, specimen TCGA-CL-4957-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Accession Number: [REDACTED]
Type: Surgical Pathology
Specimen Type: Colon
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

Report Status: Final

TCGA-CL-4957

CASE: [REDACTED]
PATIENT: [REDACTED]

Resident: [REDACTED]
Pathologist: [REDACTED]

PATHOLOGIC DIAGNOSIS:

SPECIMEN DESIGNATED "LOW ANTERIOR RESECTION":

ADENOCARCINOMA OF THE RECTUM, moderately differentiated, low grade
(4.8 cm).
Tumor extends through the muscularis into perirectal adipose tissue.
Tumor extends focally to the radial soft tissue resection margin.
Tumor extends to within 1.5 cm of the distal resection margin and
16 cm of the proximal margin.
METASTATIC ADENOCARCINOMA in two of fourteen lymph nodes (2:14).
AJCC Classification [REDACTED] T3 N1 MX.

CLINICAL DATA:

History: Rectal mass.
Operation: Low anterior resection, temp ileostomy/colectomy.
Operative Findings: Not provided.
Clinical Diagnosis: Rectal mass.

TISSUE SUBMITTED:

A/1) low anterior resection (Open and Return, and Tissue Bank).

GROSS DESCRIPTION:

The specimen is received fresh, and labeled with the patient's name and unit number, and "#1. Low anterior resection (open and return and tissue bank)", and consists of a single colectomy specimen (26.0 cm in length, 4.5 cm in diameter) with two surgical resection margins (proximal 4.0 cm in length, inked blue; distal 4.5 cm in length, inked black). There is a 26.0 cm in length mesentery present along the surface of the colon. There is a single red/brown ulcerating lesion (4.8 x 4.1 cm) located 1.5 cm from the distal surgical resection margin and 16.0 cm from the proximal surgical resection margin. There is serosal puckering opposite the center of the mass. No other lesions are seen in the mucosa, which is otherwise smooth and glistening. The mass is seen to be invading into the muscularis wall grossly. Twenty one lymph node candidates are present in the pericolonic soft tissue, the largest measuring 0.6 cm in greatest dimension. Representative sections of the tumor and normal colon are submitted for tissue banking as well as for histologic examination.

Micro A1: Proximal surgical resection margin, 1 frag, RSS.
Micro A2: Distal resection margin with tumor, 1 frag, RSS.
Micro A3: Tumor with normal adjacent colonic mucosa, 1 frag, RSS.
Micro A4: Tumor with deep muscularis infiltration, 1 frag, RSS.
Micro A5: Tumor with deep muscularis invasion, 1 frag, RSS.
Micro A6: Normal colonic mucosa located between tumor and proximal resection margin, 1 frag, RSS.
Micro A7: 6 lymph node candidates, 6 frags, ESS.
Micro A8: 5 lymph node candidates, 5 frags, ESS.
Micro A9: 1 lymph node candidate, bisected, 2 frags, ESS.
Micro A10: 2 lymph node candidates, 2 frags, ESS.
Micro A11: 5 lymph node candidates, 5 frags, ESS.
Micro A12: 1 lymph node candidate, bisected, 2 frags, ESS.
Micro A13: 2 lymph node candidates, 2 frags, ESS.

CASE NUMBER: [REDACTED]

[page 2 of 2]
Pathology Report

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Final Diagnosis by [REDACTED] Electronically signed [REDACTED]

Source: NCI Genomic Data Commons file 3cdfd376-3c37-4501-8a11-bb46e70e53c4 (TCGA-CL-4957.9719B669-9A69-44F9-B4C5-524E89343334.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).